Somatic mutation profile of tumor specimen TARGET-40-0A4I9K-01A (aliquot TARGET-40-0A4I9K-01A-01D) from TARGET case TARGET-40-0A4I9K, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 22.6 years (8,237 days).
Specimen TARGET-40-0A4I9K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8130665a-78e4-44d2-874e-8930168e8f61.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-0A4I9K-10A (Blood Derived Normal), aliquot TARGET-40-0A4I9K-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d1bddc0-2192-4196-ac3a-09e5e6219d06

The open-access MAF lists 38 somatic variants for this specimen: 23 protein-altering or splice-affecting, 6 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 6, 3'UTR 3, RNA 3, Nonsense Mutation 2, Intron 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 95/143 reads (66%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs764146326, CD137626, CM076566, CM153816, COSV52671054, COSV52674651, COSV52678614; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP10D | c.848A>G p.N283S | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1560430191; called by muse, mutect2, varscan2
- CARD16 | c.117G>C p.E39D | Missense Mutation (SNP) | VAF 105/365 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as rs61739405; called by muse, varscan2
- CDH10 | c.1429G>C p.V477L | Missense Mutation (SNP) | VAF 73/155 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs74795908; called by muse, varscan2
- CFAP65 | c.1022G>A p.C341Y | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV99838220; called by muse, mutect2, varscan2
- MUC16 | c.36446G>A p.R12149H | Missense Mutation (SNP) | VAF 260/566 reads (46%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.072); catalogued as rs756454229, COSV101198392; called by muse, mutect2
- ROM1 | c.929T>A p.L310H | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1290250771; called by muse, mutect2, varscan2
- CASP1 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 119/400 reads (30%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- CYP8B1 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DENND5B | c.1989G>C p.L663F | Missense Mutation (SNP) | VAF 32/242 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GJA5 | c.262C>G p.P88A | Missense Mutation (SNP) | VAF 53/250 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LCN12 | c.120G>T p.Q40H | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MUC16 | c.22943A>C p.E7648A | Missense Mutation (SNP) | VAF 19/211 reads (9%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.222); called by muse, mutect2
- OAZ3 | c.152C>G p.P51R | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRB3 | c.595C>A p.P199T | Missense Mutation (SNP) | VAF 49/427 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- PRKAR2B | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- RIMBP2 | c.2812G>A p.E938K | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); called by muse, varscan2
- SDK1 | c.2515A>G p.T839A | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SERPINE2 | c.310A>T p.N104Y | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- SETD2 | c.5791C>T p.Q1931* | Nonsense Mutation (SNP) | VAF 99/222 reads (45%) | called by muse, mutect2, varscan2
- TRAPPC3L | c.96G>T p.K32N | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.54); called by muse, mutect2
- VWA5A | c.2265G>A p.W755* | Nonsense Mutation (SNP) | VAF 23/161 reads (14%) | called by muse, mutect2, varscan2
- ZNF671 | c.197T>C p.L66P | Missense Mutation (SNP) | VAF 43/342 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- LAMC1 | c.780A>G p.G260= | Silent (SNP) | VAF 33/134 reads (25%) | called by muse, mutect2, varscan2
- MRGPRX4 | c.342C>T p.S114= | Silent (SNP) | VAF 102/320 reads (32%) | catalogued as rs774403101, COSV58591158; called by muse, mutect2, varscan2
- PCNX2 | c.2460T>A p.I820= | Silent (SNP) | VAF 38/246 reads (15%) | catalogued as COSV99269980; called by muse, mutect2, varscan2
- PLD5 | c.726C>A p.S242= (on ENST00000442594; = p.S180= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/101 reads (20%) | catalogued as COSV59133962; called by muse, mutect2, varscan2
- PODN | c.1149G>A p.L383= (on ENST00000395871; = p.L335= on NM_153703.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 32/274 reads (12%) | called by muse, mutect2
- RELN | c.8019C>A p.T2673= | Silent (SNP) | VAF 31/119 reads (26%) | called by muse, mutect2, varscan2
- ADGRG6 | c.*60G>T | 3'UTR (SNP) | VAF 49/365 reads (13%) | catalogued as rs1226710696; called by muse, mutect2, varscan2
- ADGRL3 | chr4:61497216 G>C | 5'Flank (SNP) | VAF 6/81 reads (7%) | called by muse, mutect2
- CARD16 | c.8-50G>C | Intron (SNP) | VAF 72/241 reads (30%) | called by muse, varscan2
- ITGA8 | c.2211+9G>T | Intron (SNP) | VAF 19/104 reads (18%) | called by muse, mutect2, varscan2
- MUC20P1 | n.831T>C | RNA (SNP) | VAF 50/602 reads (8%) | catalogued as rs28461405; called by muse, mutect2
- NOD2 | c.*41G>C | 3'UTR (SNP) | VAF 24/96 reads (25%) | called by muse, mutect2, varscan2
- OR4K11P | n.711G>T | RNA (SNP) | VAF 20/201 reads (10%) | called by muse, mutect2
- OR6K6 | c.*10C>G | 3'UTR (SNP) | VAF 26/118 reads (22%) | catalogued as rs758212443; called by muse, varscan2
- OR7E5P | n.270T>C | RNA (SNP) | VAF 74/275 reads (27%) | called by muse, mutect2, varscan2
